Somatic mutation profile of tumor specimen MMRF_1016_1_BM_CD138pos (aliquot MMRF_1016_1_BM_CD138pos_T1_KBS5U_L02999) from MMRF case MMRF_1016, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.2 years (20,534 days).
Specimen MMRF_1016_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 557039f1-e32e-4955-aa6a-1413836ff857.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1016_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1016_1_PB_WBC_C3_KBS5U_L03007; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6eec7512-b690-4da4-b783-a1b9c6c375e5

The open-access MAF lists 125 somatic variants for this specimen: 51 protein-altering or splice-affecting, 11 silent, 63 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, 3'UTR 36, Silent 11, 5'UTR 10, Intron 10, Splice Region 5, Nonsense Mutation 5, 5'Flank 4, Splice Site 2, RNA 2, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5012del p.N1671Ifs*4 (on ENST00000272895 / NM_173076.3; = p.N1353Ifs*4 on NM_015657.3) | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | catalogued as rs387906285, CD051281; ClinVar: pathogenic; called by mutect2, varscan2
- ABCA4 | c.6389T>C p.M2130T | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as CM128917; called by muse, mutect2, varscan2
- AMOTL2 | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 43/67 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs745587729; called by muse, mutect2, varscan2
- ATP6V1B1 | c.119-7C>A | Splice Region (SNP) | VAF 26/43 reads (60%) | catalogued as rs782328415; called by muse, mutect2, varscan2
- C1R | c.467-8C>T | Splice Region (SNP) | VAF 11/97 reads (11%) | catalogued as rs1356187339; called by muse, mutect2, varscan2
- CELSR3 | c.1690G>A p.V564M | Missense Mutation (SNP) | VAF 56/197 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1278475307, COSV51142676; called by muse, mutect2, varscan2
- COL4A2 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.21); catalogued as COSV64634964; called by muse, mutect2, varscan2
- DGKI | c.467C>A p.A156E | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.62); PolyPhen benign (0.028); catalogued as COSV99934658; called by muse, mutect2, varscan2
- FAT1 | c.9182C>T p.T3061M | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs762496253; called by muse, mutect2, varscan2
- HCFC1 | c.5393C>T p.P1798L | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1557112422; called by muse, mutect2
- KIF20B | c.3777-1G>C p.X1259_splice (on ENST00000371728 / NM_001284259.2; = p.X1219_splice on NM_016195.4) | Splice Site (SNP) | VAF 18/74 reads (24%) | catalogued as rs761442787; called by muse, mutect2, varscan2
- OGT | c.2861G>A p.R954Q | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV101035579, COSV65481013, COSV65482385; called by muse, mutect2, varscan2
- PRDM16 | c.3569C>T p.P1190L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs755588843; called by mutect2, varscan2
- RFC4 | c.875T>C p.V292A | Missense Mutation (SNP) | VAF 123/208 reads (59%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs2066497; called by muse, mutect2, varscan2
- RFX2 | c.838C>T p.R280W | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1354676993, COSV57940176, COSV57944068; called by muse, mutect2
- SCN7A | c.652C>G p.P218A | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as COSV69267984; called by muse, mutect2
- SLC12A8 | c.472C>T p.R158* | Nonsense Mutation (SNP) | VAF 32/190 reads (17%) | catalogued as rs778614400; called by muse, mutect2, varscan2
- TDRD15 | c.4430A>T p.K1477M | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV68267509; called by muse, mutect2, varscan2
- TRPV5 | c.1518C>T p.S506= | Splice Region (SNP) | VAF 45/105 reads (43%) | catalogued as rs140469115; called by muse, mutect2, varscan2
- ZC3H18 | c.952C>T p.R318* | Nonsense Mutation (SNP) | VAF 6/134 reads (4%) | catalogued as COSV104396081; called by muse, mutect2
- ACTG1 | c.207C>A p.Y69* | Nonsense Mutation (SNP) | VAF 95/167 reads (57%) | called by muse, mutect2, varscan2
- ANK3 | c.4074+5C>A | Splice Region (SNP) | VAF 29/58 reads (50%) | called by muse, mutect2, varscan2
- C9orf40 | c.248G>A p.S83N | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2
- CEP76 | c.325T>A p.Y109N | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- COL4A4 | c.995G>A p.G332E | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTIF | c.940C>T p.Q314* | Nonsense Mutation (SNP) | VAF 28/90 reads (31%) | called by muse, mutect2, varscan2
- EIF2B2 | c.665T>A p.I222N | Missense Mutation (SNP) | VAF 65/141 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ENTPD3 | c.369G>T p.Q123H | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FAM169A | c.549G>C p.M183I | Missense Mutation (SNP) | VAF 19/439 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.067); called by muse, mutect2
- FGFR3 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FGFR3 | c.930+2_930+21del p.X310_splice | Splice Site (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- FLG2 | c.2609G>C p.G870A | Missense Mutation (SNP) | VAF 29/299 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.189); called by muse, mutect2
- FSIP2 | c.8970A>T p.Q2990H | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HELQ | c.1322G>A p.G441E | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- LPP | c.17G>A p.W6* | Nonsense Mutation (SNP) | VAF 349/528 reads (66%) | called by muse, mutect2, varscan2
- LTB | c.208+6A>T | Splice Region (SNP) | VAF 143/230 reads (62%) | called by muse, varscan2
- NBEA | c.8020C>A p.Q2674K | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- PAPOLA | c.256C>A p.P86T | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PHKB | c.3221T>A p.M1074K | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- POLR3G | c.34T>C p.Y12H | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- PRDM5 | c.24C>G p.D8E | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRSS36 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.579); called by muse, mutect2
- RNFT2 | c.1016T>G p.L339R | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- SRCAP | c.4915G>A p.G1639R | Missense Mutation (SNP) | VAF 100/217 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.523); called by muse, varscan2
- TFE3 | c.8A>G p.H3R | Missense Mutation (SNP) | VAF 43/47 reads (91%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- TMPRSS11A | c.538A>C p.K180Q | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.39); PolyPhen probably damaging (1); called by muse, mutect2
- USF3 | c.5911A>G p.N1971D | Missense Mutation (SNP) | VAF 105/166 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- VASN | c.272T>A p.L91Q | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- VEGFA | c.242T>G p.M81R (on ENST00000523873 / NM_001171623.1; = p.M261R on NM_003376.6) | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ZFP36L2 | c.653C>A p.A218E | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZFP36L2 | c.652G>T p.A218S | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ABCB5 | c.252T>G p.T84= | Silent (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2, varscan2
- B4GALT7 | c.738G>A p.S246= | Silent (SNP) | VAF 43/159 reads (27%) | catalogued as rs761285141; called by muse, mutect2, varscan2
- CABLES2 | c.1143G>A p.V381= | Silent (SNP) | VAF 5/65 reads (8%) | catalogued as rs1212602095; called by muse, mutect2
- DTX1 | c.21T>G p.G7= | Silent (SNP) | VAF 14/24 reads (58%) | called by muse, mutect2, varscan2
- HECTD4 | c.516A>G p.L172= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as rs1479201666; called by muse, mutect2, varscan2
- IGHV2-70 | c.54A>G p.L18= | Silent (SNP) | VAF 41/45 reads (91%) | catalogued as rs187704106; called by muse, varscan2
- LRP2 | c.11481T>G p.S3827= | Silent (SNP) | VAF 17/69 reads (25%) | called by muse, mutect2, varscan2
- PTCHD4 | c.876C>T p.S292= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as COSV59782209; called by muse, mutect2
- RREB1 | c.4614G>A p.R1538= | Silent (SNP) | VAF 6/121 reads (5%) | called by muse, mutect2
- ZNF577 | c.921C>T p.F307= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as rs868727856, COSV56814933, COSV56818225; called by muse, mutect2, varscan2
- ZSWIM3 | c.468A>G p.Q156= | Silent (SNP) | VAF 13/67 reads (19%) | called by muse, mutect2, varscan2
- ACAA2 | c.*278T>A | 3'UTR (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2
- ADCY2 | c.*2199C>A | 3'UTR (SNP) | VAF 10/91 reads (11%) | called by muse, mutect2, varscan2
- ADCY7 | c.*502A>C | 3'UTR (SNP) | VAF 24/52 reads (46%) | called by muse, mutect2, varscan2
- ADH1B | c.*1820G>T | 3'UTR (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- ADPGK | c.-78C>T | 5'UTR (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2
- ARHGAP31 | c.-313C>T | 5'UTR (SNP) | VAF 21/55 reads (38%) | called by muse, mutect2, varscan2
- ARHGAP44 | c.*662C>T | 3'UTR (SNP) | VAF 17/76 reads (22%) | called by muse, mutect2, varscan2
- ATP5MPL | c.-1+334C>T | Intron (SNP) | VAF 37/83 reads (45%) | called by muse, mutect2, varscan2
- BNIP3P1 | n.170G>A | RNA (SNP) | VAF 10/16 reads (63%) | called by muse, mutect2, varscan2
- CMPK2 | chr2:6865999 G>A | 5'Flank (SNP) | VAF 39/79 reads (49%) | called by muse, mutect2, varscan2
- DYNC2I2 | c.703+73G>A | Intron (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- ERH | c.-16A>G | 5'UTR (SNP) | VAF 38/67 reads (57%) | called by muse, mutect2, varscan2
- FBRSL1 | c.*562dup | 3'UTR (INS) | VAF 8/38 reads (21%) | called by mutect2, pindel, varscan2
- FXYD5 | c.200-1005T>A | Intron (SNP) | VAF 23/333 reads (7%) | called by muse, mutect2
- GPR4 | c.*6G>A | 3'UTR (SNP) | VAF 26/176 reads (15%) | catalogued as rs1322640487, COSV59918445; called by muse, mutect2, varscan2
- GSTM5 | c.*446C>T | 3'UTR (SNP) | VAF 47/207 reads (23%) | called by muse, mutect2, varscan2
- GYG2 | c.*1386C>T | 3'UTR (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- HAUS6P1 | n.59C>G | RNA (SNP) | VAF 16/74 reads (22%) | called by muse, mutect2, varscan2
- HSD11B2 | c.*508T>A | 3'UTR (SNP) | VAF 5/20 reads (25%) | catalogued as rs5481; called by muse, mutect2, varscan2
- IQCF6 | chr3:51779221 C>T | 5'Flank (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- LARGE1 | chr22:33273008 A>C | 3'Flank (SNP) | VAF 25/51 reads (49%) | called by muse, mutect2, varscan2
- LCA5 | c.*1168C>A | 3'UTR (SNP) | VAF 46/128 reads (36%) | called by muse, mutect2, varscan2
- LTB | c.163-78G>C | Intron (SNP) | VAF 174/316 reads (55%) | catalogued as COSV53002650; called by muse, varscan2
- MED12L | c.*650A>C | 3'UTR (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851166 G>A | 5'Flank (SNP) | VAF 83/148 reads (56%) | catalogued as rs545455545; called by muse, mutect2, varscan2
- MPV17L2 | c.*30C>T | 3'UTR (SNP) | VAF 163/240 reads (68%) | called by muse, mutect2, varscan2
- NAV1 | c.-382C>T | 5'UTR (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2, varscan2
- NOX4 | c.*1716G>C | 3'UTR (SNP) | VAF 67/119 reads (56%) | called by muse, mutect2, varscan2
- NPAS4 | c.-21G>A | 5'UTR (SNP) | VAF 11/61 reads (18%) | called by muse, mutect2, varscan2
- NUMA1 | c.*241C>T | 3'UTR (SNP) | VAF 14/50 reads (28%) | called by muse, mutect2, varscan2
- ODC1 | c.*210_*216del | 3'UTR (DEL) | VAF 12/68 reads (18%) | called by mutect2, pindel, varscan2
- OPA1 | c.2983+1346C>G | Intron (SNP) | VAF 17/231 reads (7%) | called by muse, mutect2
- PEX2 | c.*1496A>G | 3'UTR (SNP) | VAF 60/125 reads (48%) | called by muse, mutect2, varscan2
- PLBD1 | c.-184A>C | 5'UTR (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- POFUT2 | c.1137-253G>A | Intron (SNP) | VAF 28/48 reads (58%) | catalogued as rs1027198528; called by muse, mutect2, varscan2
- PRDM14 | c.*325G>T | 3'UTR (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- PRIMA1 | c.*1533G>A | 3'UTR (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2, varscan2
- PTAR1 | c.*5502G>A | 3'UTR (SNP) | VAF 84/170 reads (49%) | catalogued as rs1028131158; called by muse, mutect2, varscan2
- RANBP17 | c.2231+215G>A | Intron (SNP) | VAF 5/63 reads (8%) | catalogued as rs925726202; called by muse, mutect2
- RBM4 | c.*399A>G | 3'UTR (SNP) | VAF 10/41 reads (24%) | catalogued as rs1404887846; called by muse, mutect2, varscan2
- REPS1 | c.*446A>T | 3'UTR (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- SCGN | c.*198C>T | 3'UTR (SNP) | VAF 15/260 reads (6%) | called by muse, mutect2
- SCUBE3 | c.*1056del | 3'UTR (DEL) | VAF 10/68 reads (15%) | called by mutect2, pindel, varscan2
- SEMA6C | c.*545C>T | 3'UTR (SNP) | VAF 25/151 reads (17%) | catalogued as rs1196723728; called by muse, mutect2, varscan2
- SHISAL2B | c.-71G>A | 5'UTR (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- SLC2A12 | c.*36A>T | 3'UTR (SNP) | VAF 20/74 reads (27%) | called by muse, mutect2, varscan2
- SLC6A20 | c.*3367A>G | 3'UTR (SNP) | VAF 27/91 reads (30%) | called by muse, mutect2, varscan2
- SMC5 | c.*2189C>T | 3'UTR (SNP) | VAF 18/27 reads (67%) | catalogued as rs923960334; called by muse, mutect2, varscan2
- SOSTDC1 | c.-19A>G | 5'UTR (SNP) | VAF 20/122 reads (16%) | catalogued as COSV61049385; called by muse, mutect2, varscan2
- SUB1 | c.*12T>G | 3'UTR (SNP) | VAF 22/173 reads (13%) | called by muse, mutect2, varscan2
- TCEANC | c.*208C>T | 3'UTR (SNP) | VAF 17/17 reads (100%) | called by muse, mutect2, varscan2
- TGFBR1 | c.*2100_*2101insG | 3'UTR (INS) | VAF 19/121 reads (16%) | catalogued as rs1234828152; called by mutect2, varscan2
- TLCD1 | chr17:28726833 A>G | 5'Flank (SNP) | VAF 15/88 reads (17%) | catalogued as rs1467174426; called by muse, mutect2, varscan2
- TLE4 | c.-167C>G | 5'UTR (SNP) | VAF 12/36 reads (33%) | called by muse, varscan2
- TLL1 | c.*347A>G | 3'UTR (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2
- TLR4 | c.*351G>T | 3'UTR (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2, varscan2
- TMSB4X | c.-41C>T | 5'UTR (SNP) | VAF 48/51 reads (94%) | catalogued as COSV66081674; called by muse, mutect2, varscan2
- TMSB4X | c.-17+252C>T | Intron (SNP) | VAF 34/35 reads (97%) | called by muse, mutect2, varscan2
- TNC | c.4579+4234T>C | Intron (SNP) | VAF 7/70 reads (10%) | catalogued as rs1185225268; called by muse, mutect2
- TRIM33 | c.*1591C>T | 3'UTR (SNP) | VAF 9/85 reads (11%) | called by muse, mutect2, varscan2
- TTC19 | c.*563A>G | 3'UTR (SNP) | VAF 29/85 reads (34%) | called by muse, mutect2, varscan2
- VOPP1 | c.54+19579G>T | Intron (SNP) | VAF 3/42 reads (7%) | catalogued as rs1316680131; called by muse, mutect2
- ZADH2 | c.*5660dup | 3'UTR (INS) | VAF 13/27 reads (48%) | catalogued as rs1000646725; called by mutect2, varscan2
